TARGET case TARGET-50-PAJMJM — High-Risk Wilms Tumor (TARGET-WT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d58be335-8f98-5518-99fa-8fa36138d836

Demographics
Sex at birth: male; Race: white; Age at index: 14 years; Vital status: Alive.

Diagnoses (1)
1. Wilms tumor: ICD-O-3 morphology code: 8960/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 14.6 years (5,319 days); Year of diagnosis: 1998; Days to last follow up: 2,924 days (8.0 years); Pediatric kidney staging: Nephrectomy specimen with tumor that is present at the surgical margin of resection or within regional lymph nodes, no distant metastasis; Wilms tumor histologic subtype: Favorable.
   Treatment given: Protocol identifier: NWTS-5.

Follow-up (2 entries)
- Days to follow up: 631 days (1.7 years); Days to first event: 631 days (1.7 years); First event: Relapse.
- Days to follow up: 2,924 days (8.0 years); Year of follow up: 2006.

Biospecimens (1 sample)
- Sample TARGET-50-PAJMJM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet WT Data), for sample TARGET-50-PAJMJM-01A:
- Histological Subtype: relapse Wilms
- Specimen Type: frozen solid tumor
- Pathology: Diagnosis Confirmed: No
- % Tumor Nuclei: Top: 10
- % Non tumor Nuclei: Top: 90
- % Cellular Tumor: Top: 5
- % Normal: Top: 0
- % Stroma: Top: 45
- % Necrosis: Top: 50
- % Tumor Nuclei: Bottom: 10
- % Non tumor Nuclei: Bottom: 90
- % Cellular Tumor: Bottom: 5
- % Normal: Bottom: 0
- % Stroma: Bottom: 45
- % Necrosis: Bottom: 50
- Pathology Pass/Fail: Fail

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2924
- Stage: III
- ICD-O-3-T: C649
- Histologic Classification of Primary Tumor: FHWT
